Somatic mutation profile of tumor specimen TCGA-22-5482-01A (aliquot TCGA-22-5482-01A-01D-1632-08) from TCGA case TCGA-22-5482, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 81.2 years (29,657 days).
Specimen TCGA-22-5482-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 264decc5-e850-4116-b019-078d90eb1705.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-22-5482-11A (Solid Tissue Normal), aliquot TCGA-22-5482-11A-01D-1632-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d14e0f3-fff5-4b05-bb7b-349267c0114b

The open-access MAF lists 182 somatic variants for this specimen: 138 protein-altering or splice-affecting, 42 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 122, Silent 42, Nonsense Mutation 8, Frame Shift Del 4, Splice Site 2, Splice Region 1, In Frame Del 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.108_110del p.F37del | In Frame Del (DEL) | VAF 17/49 reads (35%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- TP53 | c.376-2A>G p.X126_splice | Splice Site (SNP) | VAF 19/25 reads (76%) | hotspot (GDC flag); catalogued as rs786202799, CS114003, COSV52689235, COSV52691326, COSV53121815, COSV53758902; ClinVar: likely pathogenic; called by muse, mutect2
- ZDHHC9 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137852215, CM072123, COSV64097494; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC11 | c.1742C>T p.A581V | Missense Mutation (SNP) | VAF 89/160 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV62326124; called by muse, mutect2, varscan2
- ACSS3 | c.965G>T p.W322L | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV54102249; called by muse, mutect2, varscan2
- ACTR10 | c.592G>A p.V198M | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.905); catalogued as COSV54297620; called by muse, mutect2
- AMER3 | c.1106C>A p.T369K | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV58465190, COSV58470589; called by muse, mutect2, varscan2
- AOAH | c.807C>A p.H269Q | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51751188; called by muse, mutect2, varscan2
- ARHGAP35 | c.3176T>C p.L1059S | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.281); catalogued as rs770808622, COSV68336026; called by muse, mutect2, varscan2
- ARRDC2 | c.516G>C p.K172N | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55846154; called by muse, mutect2, varscan2
- ASCC3 | c.3430A>T p.K1144* | Nonsense Mutation (SNP) | VAF 26/85 reads (31%) | catalogued as COSV61234234; called by muse, mutect2, varscan2
- ATF6B | c.1336G>T p.E446* | Nonsense Mutation (SNP) | VAF 17/34 reads (50%) | catalogued as COSV64352744; called by muse, mutect2, varscan2
- ATF7IP | c.2132C>A p.P711Q | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.387); catalogued as COSV53778616; called by muse, mutect2, varscan2
- ATG2A | c.1583C>G p.P528R | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV65969013; called by muse, mutect2, varscan2
- ATP7A | c.4278A>G p.I1426M | Missense Mutation (SNP) | VAF 63/92 reads (68%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58454709; called by muse, mutect2, varscan2
- BPTF | c.4206A>T p.E1402D | Missense Mutation (SNP) | VAF 55/86 reads (64%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); catalogued as COSV58847908; called by muse, mutect2, varscan2
- CAMSAP2 | c.645G>A p.K215= | Splice Region (SNP) | VAF 7/17 reads (41%) | catalogued as COSV52678336, COSV99374296; called by muse, mutect2, varscan2
- CAPSL | c.158A>G p.D53G | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.114); catalogued as rs1188137226, COSV68439559; called by muse, mutect2
- CCK | c.215-2A>G p.X72_splice | Splice Site (SNP) | VAF 14/30 reads (47%) | catalogued as COSV100589088; called by muse, mutect2, varscan2
- CCSER2 | c.1511C>T p.S504F | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56513116; called by muse, mutect2
- CD46 | c.181G>C p.D61H | Missense Mutation (SNP) | VAF 76/123 reads (62%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.961); catalogued as COSV59735738; called by muse, mutect2, varscan2
- CDH20 | c.2149G>C p.A717P | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53008554, COSV53018843, COSV53020216; called by muse, mutect2
- COG7 | c.1534G>T p.G512C | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV56153542; called by muse, mutect2, varscan2
- COL4A4 | c.3841C>A p.P1281T | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV61637081; called by muse, mutect2, varscan2
- COL6A5 | c.7509G>A p.M2503I (on ENST00000312481; = p.M2499I on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1302629444, COSV55217475; called by muse, mutect2, varscan2
- CPS1 | c.2590C>A p.L864I | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV51800595; called by muse, mutect2, varscan2
- CRYBG1 | c.5160A>G p.I1720M | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.379); catalogued as rs987622480, COSV64814860; called by muse, mutect2, varscan2
- CSMD3 | c.8582A>G p.H2861R (on ENST00000297405 / NM_001363185.1; = p.H2692R on NM_052900.3) | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.189); catalogued as COSV52331374; called by muse, mutect2, varscan2
- CSMD3 | c.7601C>T p.S2534F (on ENST00000297405 / NM_001363185.1; = p.S2430F on NM_052900.3) | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV52331397; called by muse, mutect2, varscan2
- CTNNA2 | c.2141T>C p.L714P | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58183951; called by muse, mutect2, varscan2
- CYC1 | c.664C>G p.P222A | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59645168; called by muse, mutect2, varscan2
- DCAF4L2 | c.103G>T p.G35C | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60479228; called by muse, mutect2, varscan2
- DDI2 | c.271T>G p.L91V | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.079); catalogued as COSV60781663; called by muse, mutect2, varscan2
- DNAH3 | c.4285G>A p.G1429S | Missense Mutation (SNP) | VAF 38/64 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54555299; called by muse, mutect2, varscan2
- DNAH8 | c.5557A>G p.T1853A | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV59483308; called by muse, mutect2, varscan2
- DPP6 | c.1186G>T p.V396L (on ENST00000377770 / NM_001364500.2; = p.V334L on NM_001936.5) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs1451438931, COSV59629101, COSV59647742; called by muse, mutect2, varscan2
- DSEL | c.2300A>C p.K767T | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as COSV59495212; called by muse, mutect2, varscan2
- DUXA | c.10G>T p.D4Y | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.543); catalogued as COSV73729906; called by muse, mutect2, varscan2
- EBF3 | c.980C>G p.T327S (on ENST00000355311 / NM_001375392.1; = p.T318S on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV62482412; called by muse, mutect2
- EGF | c.2965G>T p.V989L | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.093); catalogued as COSV54485326; called by muse, mutect2, varscan2
- EHBP1 | c.2204A>T p.E735V | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.25); catalogued as COSV50440894; called by muse, mutect2, varscan2
- EML5 | c.997G>T p.V333F | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV61352237; called by muse, mutect2, varscan2
- EVI5 | c.1560A>C p.E520D | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.777); catalogued as COSV64830441; called by muse, mutect2, varscan2
- F13B | c.517A>C p.K173Q | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.424); catalogued as COSV66375876; called by muse, mutect2, varscan2
- FAM81A | c.107G>A p.R36K | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV55680994; called by muse, mutect2
- FCAR | c.807C>A p.S269R | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.365); catalogued as COSV62031607; called by muse, mutect2
- GABRA3 | c.1258G>A p.A420T | Missense Mutation (SNP) | VAF 70/103 reads (68%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.631); catalogued as rs202150301, COSV64805880; called by muse, mutect2, varscan2
- GABRB3 | c.1195G>T p.G399* | Nonsense Mutation (SNP) | VAF 7/103 reads (7%) | catalogued as COSV100162285, COSV54685523; called by muse, mutect2
- GABRB3 | c.350G>T p.W117L | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54685545; called by muse, mutect2, varscan2
- GLUL | c.977C>G p.P326R | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59383526; called by muse, mutect2, varscan2
- IRF8 | c.826C>A p.R276S | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV51896789, COSV51900805; called by muse, mutect2, varscan2
- ISCA1 | c.356G>A p.G119E | Missense Mutation (SNP) | VAF 48/204 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.18); catalogued as rs755775475, COSV58182245; called by muse, mutect2, varscan2
- ITGA2B | c.134C>A p.P45H | Missense Mutation (SNP) | VAF 53/88 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV52235442; called by muse, mutect2, varscan2
- KCNN2 | c.1531G>T p.E511* (on ENST00000264773; = p.E723* on NM_021614.4) | Nonsense Mutation (SNP) | VAF 28/83 reads (34%) | catalogued as COSV53292610; called by muse, mutect2, varscan2
- KCTD3 | c.783G>T p.W261C | Missense Mutation (SNP) | VAF 88/155 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52071094; called by muse, mutect2, varscan2
- KDM2A | c.2258G>A p.R753H | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV58191644; called by muse, mutect2, varscan2
- KLF12 | c.1067G>A p.W356* | Nonsense Mutation (SNP) | VAF 13/61 reads (21%) | catalogued as COSV66582378; called by muse, mutect2, varscan2
- KMT2D | c.6945C>G p.H2315Q | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.601); catalogued as rs764686162, COSV56491126; called by muse, mutect2, varscan2
- LCT | c.3336C>A p.Y1112* | Nonsense Mutation (SNP) | VAF 36/102 reads (35%) | catalogued as COSV51558272; called by muse, mutect2, varscan2
- LRFN2 | c.1526G>T p.G509V | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57835168; called by muse, mutect2, varscan2
- LRIT2 | c.1064C>A p.S355Y | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.69); PolyPhen benign (0.086); catalogued as COSV60566864; called by muse, mutect2, varscan2
- LYST | c.8703G>T p.E2901D | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV67714774; called by muse, mutect2, varscan2
- MAG | c.841C>T p.R281W | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.917); catalogued as rs200404904, COSV62703181; called by muse, mutect2, varscan2
- MFSD2A | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65686689; called by muse, mutect2, varscan2
- MNX1 | c.986G>A p.G329E | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1305647412, COSV53319388; called by mutect2, varscan2
- MUC16 | c.27291C>A p.D9097E | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.303); catalogued as rs1372297081, COSV67496828; called by muse, mutect2, varscan2
- MUC16 | c.10768G>T p.D3590Y | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.452); catalogued as COSV67496833; called by muse, mutect2, varscan2
- NCAM2 | c.1900G>A p.D634N | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); catalogued as rs1455140442, COSV53066275, COSV53106297; called by muse, varscan2
- NCOA2 | c.2432A>T p.D811V | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as COSV51223587; called by muse, mutect2, varscan2
- NIBAN3 | c.1804G>A p.D602N | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.29); catalogued as COSV56314246; called by muse, mutect2
- NKAIN3 | c.404T>A p.V135D | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV60686917; called by muse, mutect2, varscan2
- NKX2-2 | c.447G>T p.Q149H | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV65820428; called by muse, mutect2, varscan2
- NOS1AP | c.980C>G p.A327G | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as COSV62633420, COSV62640568; called by muse, mutect2, varscan2
- NPEPL1 | c.532G>A p.V178M | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as rs373363596; called by muse, mutect2, varscan2
- NRAP | c.2832A>C p.L944F (on ENST00000359988 / NM_001322945.2; = p.L909F on NM_006175.4) | Missense Mutation (SNP) | VAF 55/167 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63494284; called by muse, mutect2, varscan2
- OR10AG1 | c.145C>A p.P49T | Missense Mutation (SNP) | VAF 42/73 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV56635083; called by muse, mutect2
- OR1C1 | c.113C>A p.T38N | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV68716457; called by muse, mutect2, varscan2
- OR5AK2 | c.719C>T p.T240I | Missense Mutation (SNP) | VAF 62/96 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58805476; called by muse, mutect2, varscan2
- OR5H15 | c.255C>A p.F85L | Missense Mutation (SNP) | VAF 17/195 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV62949150; called by muse, mutect2
- OSBPL8 | c.492G>T p.W164C | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53887610, COSV53889702; called by muse, mutect2, varscan2
- PABPC5 | c.985A>T p.S329C | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as rs749117182, COSV57040579; called by muse, mutect2, varscan2
- PANX3 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 35/50 reads (70%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs1292202307, COSV52511520, COSV99421125; called by muse, mutect2, varscan2
- PCDHA7 | c.1415G>T p.C472F | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.769); catalogued as rs781995630; called by muse, mutect2
- PCDHB10 | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.013); catalogued as COSV53384312; called by muse, mutect2, varscan2
- PKD1 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs899447972, COSV51926625; called by muse, mutect2, varscan2
- PKHD1L1 | c.4478A>C p.Q1493P | Missense Mutation (SNP) | VAF 12/225 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.181); catalogued as COSV65749931; called by muse, mutect2
- PLAGL2 | c.1370C>A p.P457H | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.907); catalogued as COSV55789929; called by muse, mutect2, varscan2
- PLXND1 | c.3377C>T p.S1126F | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV60711359, COSV60719837; called by muse, mutect2
- POTEF | c.2561A>T p.D854V | Missense Mutation (SNP) | VAF 55/118 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV62544838; called by muse, mutect2, varscan2
- PPP1R9A | c.1771G>T p.E591* | Nonsense Mutation (SNP) | VAF 23/56 reads (41%) | catalogued as COSV56880598, COSV56912818; called by muse, mutect2
- PPP2R5B | c.165C>G p.N55K | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV51213522; called by muse, mutect2, varscan2
- PPP3R2 | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 72/140 reads (51%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV62458770; called by muse, mutect2, varscan2
- RABGAP1 | c.1247C>T p.T416I | Missense Mutation (SNP) | VAF 46/205 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.834); catalogued as COSV65396152; called by muse, mutect2, varscan2
- RASA1 | c.2714T>A p.I905N | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV57202913; called by muse, mutect2, varscan2
- RASGRF2 | c.524T>C p.I175T | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV54140702; called by muse, mutect2, varscan2
- RGS12 | c.3808A>C p.S1270R | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.005); catalogued as COSV58757678; called by muse, mutect2, varscan2
- RNF213 | c.11975T>G p.F3992C | Missense Mutation (SNP) | VAF 62/99 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as rs890910478, COSV60409987; called by muse, mutect2, varscan2
- ROS1 | c.2366T>C p.V789A | Missense Mutation (SNP) | VAF 53/173 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.912); catalogued as COSV63862125; called by muse, mutect2, varscan2
- RTN1 | c.2040G>T p.Q680H | Missense Mutation (SNP) | VAF 35/54 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV50751660; called by muse, mutect2, varscan2
- S1PR2 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58485967; called by muse, mutect2, varscan2
- SAMD7 | c.862G>T p.A288S | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.072); catalogued as COSV59421836; called by muse, mutect2
- SHCBP1L | c.572A>G p.Y191C | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.181); catalogued as rs1462589736, COSV62357438; called by muse, mutect2, varscan2
- SIPA1L3 | c.4537G>T p.D1513Y | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55925147; called by muse, mutect2, varscan2
- SLC45A4 | c.1193A>T p.Y398F (on ENST00000517878 / NM_001286646.2; = p.Y347F on NM_001080431.2) | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as COSV50194167; called by muse, mutect2, varscan2
- SLX4 | c.518C>G p.S173C | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV53568481, COSV53569136; called by muse, mutect2, varscan2
- SORCS2 | c.2731G>A p.G911S | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as rs768340326, COSV61184232; called by muse, mutect2, varscan2
- SPATA16 | c.1453C>A p.L485I | Missense Mutation (SNP) | VAF 65/453 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63533636; called by muse, mutect2, varscan2
- SPTBN4 | c.842A>G p.Y281C | Missense Mutation (SNP) | VAF 49/147 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58959811; called by muse, mutect2, varscan2
- ST3GAL6 | c.53T>A p.V18E | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV54580813, COSV54585698; called by muse, mutect2, varscan2
- TAF1L | c.4867A>G p.I1623V | Missense Mutation (SNP) | VAF 39/70 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1280832996, COSV54270900; called by muse, mutect2, varscan2
- TAF5 | c.1000C>G p.Q334E | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.043); catalogued as COSV60858230; called by muse, mutect2, varscan2
- TBX2 | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0.424); catalogued as COSV53601390; called by mutect2, varscan2
- THBS2 | c.2905C>T p.P969S | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64678133, COSV64678704; called by muse, mutect2, varscan2
- TICRR | c.2177G>T p.R726L | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV51547579, COSV51549071; called by muse, mutect2, varscan2
- TMEM200A | c.483G>C p.R161S | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51654922, COSV51660242; called by muse, mutect2, varscan2
- TPI1 | c.730A>G p.I244V (on ENST00000229270; = p.I207V on NM_000365.6) | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); catalogued as COSV51290449; called by muse, mutect2, varscan2
- TRMT1L | c.577A>G p.I193V | Missense Mutation (SNP) | VAF 50/167 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV62271986, COSV62273589; called by muse, mutect2, varscan2
- TYK2 | c.311G>T p.R104L | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV53386844, COSV53392477; called by muse, mutect2, varscan2
- UGT1A6 | c.1411C>T p.P471S | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.344); catalogued as rs377565834; called by muse, mutect2, varscan2
- UNC5C | c.440G>A p.W147* | Nonsense Mutation (SNP) | VAF 36/59 reads (61%) | catalogued as COSV71662545, COSV99070648; called by muse, mutect2, varscan2
- UNC80 | c.714C>G p.N238K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as COSV55907751; called by muse, mutect2, varscan2
- USP50 | c.499G>A p.E167K (on ENST00000616326; = p.E158K on NM_203494.5) | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT tolerated (0.27); PolyPhen benign (0.257); catalogued as COSV73214356; called by muse, mutect2, varscan2
- VPS13A | c.7705A>G p.M2569V | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as rs770600544, COSV62439965; called by muse, mutect2, varscan2
- YEATS2 | c.2173G>T p.A725S | Missense Mutation (SNP) | VAF 45/71 reads (63%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs1219115452, COSV59372950; called by muse, mutect2, varscan2
- ZFHX4 | c.1767C>A p.H589Q | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.626); catalogued as COSV51498638; called by muse, mutect2, varscan2
- ZFHX4 | c.1768C>A p.Q590K | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.487); catalogued as COSV51498643; called by muse, mutect2, varscan2
- ZFP37 | c.1059G>T p.Q353H | Missense Mutation (SNP) | VAF 91/179 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100953234, COSV65288915; called by muse, mutect2, varscan2
- ZNF143 | c.757C>T p.H253Y | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV55182890; called by muse, mutect2, varscan2
- ZNF235 | c.427G>A p.V143M | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV52158623, COSV99349796; called by muse, mutect2, varscan2
- ZNF236 | c.3801G>C p.K1267N | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV53498566; called by muse, mutect2, varscan2
- ZNF536 | c.1636C>G p.R546G | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.069); catalogued as COSV62819896, COSV62831299; called by muse, mutect2, varscan2
- ZNF74 | c.1145A>G p.H382R | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV62624551; called by muse, mutect2, varscan2
- ZNF808 | c.1732C>G p.Q578E | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.574); catalogued as COSV63121891; called by muse, mutect2, varscan2
- ABCC10 | c.3792_3795del p.D1264Efs*2 (on ENST00000372530 / NM_001198934.2; = p.D1236Efs*2 on NM_033450.2 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 76/268 reads (28%) | called by pindel, varscan2
- C3orf20 | c.1459_1480del p.V487Qfs*7 | Frame Shift Del (DEL) | VAF 17/48 reads (35%) | called by mutect2, pindel, varscan2
- H2BC9 | c.358del p.T120Pfs*27 | Frame Shift Del (DEL) | VAF 29/63 reads (46%) | called by mutect2, pindel, varscan2
- OR51B2 | c.646del p.Y216Ifs*3 | Frame Shift Del (DEL) | VAF 18/34 reads (53%) | called by mutect2, pindel, varscan2
- TPTE | c.596T>A p.L199H (on ENST00000618007 / NM_199261.4; = p.L181H on NM_199259.4) | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ACAP2 | c.1074C>A p.T358= | Silent (SNP) | VAF 26/378 reads (7%) | catalogued as rs764801694, COSV58756441; called by muse, mutect2
- ARSF | c.1425G>C p.P475= | Silent (SNP) | VAF 21/32 reads (66%) | catalogued as COSV63841240; called by muse, mutect2, varscan2
- BRINP1 | c.567T>A p.T189= | Silent (SNP) | VAF 53/98 reads (54%) | catalogued as COSV56314306; called by muse, mutect2, varscan2
- CASP8 | c.825A>G p.E275= (on ENST00000432109 / NM_033355.3; = p.E292= on NM_001228.4) | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as COSV51859964; called by muse, mutect2, varscan2
- CCDC102A | c.1545C>T p.N515= | Silent (SNP) | VAF 39/90 reads (43%) | catalogued as rs745545748, COSV50779853; called by muse, mutect2, varscan2
- CD8B | c.165G>A p.L55= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as rs762132342, COSV58928701; called by muse, mutect2, varscan2
- CEMIP | c.1065C>T p.C355= | Silent (SNP) | VAF 33/56 reads (59%) | catalogued as COSV55000946; called by muse, mutect2, varscan2
- CLPTM1 | c.348A>G p.T116= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV61613355; called by muse, mutect2, varscan2
- COL5A2 | c.2808G>T p.G936= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs141089340; called by muse, mutect2, varscan2
- CPS1 | c.2589C>A p.S863= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as COSV51825749; called by muse, mutect2, varscan2
- CYP4F11 | c.1545G>T p.R515= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV56127988, COSV56129859; called by muse, mutect2, varscan2
- DCSTAMP | c.1320G>C p.L440= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV52580364; called by muse, mutect2, varscan2
- DMD | c.8958G>A p.A2986= | Silent (SNP) | VAF 12/19 reads (63%) | catalogued as rs755815057, COSV58956592; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- DSC3 | c.1866G>T p.L622= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV64575708; called by muse, mutect2, varscan2
- DYNC1H1 | c.12018C>T p.H4006= | Silent (SNP) | VAF 31/168 reads (18%) | catalogued as COSV64137639; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.2886T>C p.D962= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV57518357; called by muse, mutect2, varscan2
- EMILIN3 | c.532C>T p.L178= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as COSV60038955; called by muse, mutect2
- EPM2AIP1 | c.210G>T p.A70= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV51625058; called by muse, mutect2, varscan2
- F10 | c.1440G>A p.E480= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as COSV65023237; called by muse, mutect2, varscan2
- GCSAML | c.36G>T p.L12= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV63579725; called by muse, mutect2
- GIPC1 | c.954C>T p.V318= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs757879595, COSV52876942; called by muse, mutect2, varscan2
- ISCA1 | c.357G>T p.G119= | Silent (SNP) | VAF 48/204 reads (24%) | catalogued as COSV58182234; called by muse, mutect2, varscan2
- KCNN2 | c.1530G>T p.L510= (on ENST00000264773; = p.L722= on NM_021614.4) | Silent (SNP) | VAF 28/85 reads (33%) | catalogued as COSV53300008; called by muse, mutect2, varscan2
- LCOR | c.4311A>G p.P1437= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV53718700; called by muse, mutect2, varscan2
- LTN1 | c.5253A>G p.T1751= | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as COSV63735448; called by muse, mutect2, varscan2
- MACF1 | c.5613A>G p.L1871= | Silent (SNP) | VAF 45/76 reads (59%) | catalogued as rs1341006328, COSV57146339; called by muse, mutect2, varscan2
- MAGI2 | c.1206G>A p.L402= | Silent (SNP) | VAF 32/105 reads (30%) | catalogued as rs1343763966, COSV62701702; called by muse, mutect2, varscan2
- MAOB | c.126G>A p.R42= | Silent (SNP) | VAF 18/27 reads (67%) | catalogued as COSV65207042; called by muse, mutect2, varscan2
- NAV3 | c.3732C>T p.A1244= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV57114632; called by muse, mutect2
- NEB | c.4545G>A p.K1515= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as COSV51463413; called by muse, mutect2
- NECTIN2 | c.243T>C p.N81= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV52980326; called by muse, mutect2, varscan2
- PGAM4 | c.528G>A p.K176= | Silent (SNP) | VAF 37/55 reads (67%) | catalogued as COSV58454699; called by muse, mutect2, varscan2
- PLXND1 | c.4230T>A p.I1410= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV60719827; called by muse, mutect2
- PNPLA8 | c.2028G>A p.L676= | Silent (SNP) | VAF 32/75 reads (43%) | catalogued as COSV57555054; called by muse, mutect2, varscan2
- SCN9A | c.3405T>A p.P1135= (on ENST00000303354; = p.P1124= on NM_002977.3) | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as COSV57626119; called by muse, mutect2, varscan2
- STAB2 | c.3811A>C p.R1271= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV66347925; called by muse, mutect2, varscan2
- SV2C | c.285C>T p.G95= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs1561229625, COSV59229971; called by muse, mutect2
- TEX44 | c.357G>A p.Q119= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as rs772613193, COSV58355607; called by muse, mutect2, varscan2
- TIE1 | c.1173C>T p.D391= | Silent (SNP) | VAF 19/29 reads (66%) | catalogued as rs759805607, COSV65248766; called by muse, mutect2, varscan2
- UNC5D | c.708C>T p.I236= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as rs764908615, COSV54767563, COSV54777646; called by muse, mutect2, varscan2
- WNT2 | c.441C>T p.D147= | Silent (SNP) | VAF 33/83 reads (40%) | catalogued as COSV55414113; called by muse, mutect2, varscan2
- XKR6 | c.1293T>C p.F431= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as COSV58659868; called by muse, mutect2, varscan2
- HTR2C | c.-80+16947C>A | Intron (SNP) | VAF 13/20 reads (65%) | catalogued as COSV52209635, COSV99351581; called by muse, mutect2, varscan2
- SNORD115-22 | n.58G>A | RNA (SNP) | VAF 22/277 reads (8%) | called by muse, mutect2
